Somatic mutation profile of tumor specimen TCGA-DU-5872-01A (aliquot TCGA-DU-5872-01A-11D-1705-08) from TCGA case TCGA-DU-5872, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 43.8 years (15,986 days).
Specimen TCGA-DU-5872-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3b97565-fca0-4576-a44e-82fb380140fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5872-10A (Blood Derived Normal), aliquot TCGA-DU-5872-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f091361b-3c0e-4f62-a3be-360e081ecd9d

The open-access MAF lists 32 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 23, Silent 5, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 47/61 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARAP1 | c.2314C>T p.R772C (on ENST00000393609 / NM_001040118.2; = p.R527C on NM_015242.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs141410764; called by muse, varscan2
- ATRX | c.6515A>C p.E2172A | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64871256, COSV64876122; called by muse, mutect2, varscan2
- BUB1 | c.895A>G p.K299E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV57063324; called by muse, mutect2, varscan2
- CCDC160 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs746777916, COSV66251600; called by muse, mutect2, varscan2
- COL11A1 | c.3833G>A p.R1278K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.952); catalogued as COSV62173704, COSV62182589; called by muse, mutect2, varscan2
- COL1A2 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51956211; called by muse, mutect2, varscan2
- CPO | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs752338320, COSV55939655; called by muse, mutect2, varscan2
- CRYGN | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs148445096; called by muse, mutect2, varscan2
- FAM161A | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56765762; called by muse, mutect2, varscan2
- LAMA3 | c.3717T>G p.L1239= | Splice Region (SNP) | VAF 16/36 reads (44%) | catalogued as COSV58068069; called by muse, mutect2, varscan2
- MYH1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs988594695, COSV55437388, COSV55438734; called by muse, mutect2
- PIAS3 | c.1702C>G p.H568D | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.84); catalogued as COSV57907231; called by muse, mutect2, varscan2
- PLCH1 | c.3098T>C p.L1033P (on ENST00000340059 / NM_001130960.2; = p.L1025P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV58195976; called by muse, mutect2, varscan2
- PLXNA3 | c.244A>G p.S82G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs142949704, COSV63754004; called by muse, mutect2, varscan2
- PROS1 | c.403A>G p.K135E | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV62398348; called by muse, mutect2, varscan2
- RERE | c.2144T>C p.I715T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV61941571; called by muse, mutect2, varscan2
- RORB | c.366G>C p.Q122H (on ENST00000396204 / NM_001365023.1; = p.Q111H on NM_006914.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.719); catalogued as COSV100974324, COSV65335569; called by muse, mutect2, varscan2
- SETX | c.1840A>G p.I614V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV56384435; called by muse, mutect2, varscan2
- SPP2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs376262894, COSV51445242; called by muse, mutect2, varscan2
- TAS1R2 | c.1793C>A p.S598* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100946207, COSV64744810; called by muse, mutect2, varscan2
- TRIM51 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as rs774419045, COSV55266233, COSV55268722; called by muse, mutect2, varscan2
- TRRAP | c.4625C>T p.T1542M (on ENST00000359863 / NM_001244580.1; = p.T1524M on NM_003496.3) | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV62843802; called by muse, mutect2, varscan2
- WDR33 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59248534; called by muse, mutect2, varscan2
- ZNF451 | c.1818G>A p.W606* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | catalogued as COSV62597579; called by muse, mutect2, varscan2
- LILRB2 | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AKAP4 | c.1767T>C p.G589= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV62074348; called by muse, mutect2, varscan2
- HDAC4 | c.3027C>T p.P1009= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV61864702; called by muse, mutect2, varscan2
- PRICKLE1 | c.873T>C p.C291= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV61543147; called by muse, mutect2, varscan2
- PSMD12 | c.852A>T p.S284= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV62065628; called by muse, mutect2, varscan2
- SPATA16 | c.1560T>C p.N520= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV63529043; called by muse, mutect2, varscan2
